Somatic mutation profile of tumor specimen HCM-BROD-0569-C43-06A (aliquot HCM-BROD-0569-C43-06A-11D-A80U-36) from HCMI case HCM-BROD-0569-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 78.3 years (28,586 days).
Specimen HCM-BROD-0569-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58efa635-f0c7-4dde-ac0c-c3cd6b1eda3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0569-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0569-C43-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86ee8184-720c-4ee5-b96a-3e99ffef5fe8

The open-access MAF lists 3,884 somatic variants for this specimen: 2,512 protein-altering or splice-affecting, 1,216 silent, 156 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,291, Silent 1,216, Nonsense Mutation 150, Intron 90, Splice Region 36, 5'Flank 24, Splice Site 16, 3'UTR 15, Frame Shift Del 11, RNA 10, 3'Flank 9, 5'UTR 8.

Variants (750 of 3,884; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72653753, CM053088; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID2 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 44/243 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57595738; called by muse, mutect2, varscan2
- ATP1A3 | c.2806G>A p.D936N (on ENST00000545399 / NM_001256214.2; = p.D923N on NM_152296.5) | Missense Mutation (SNP) | VAF 109/325 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); catalogued as rs267606670, CM094577, CM127594, COSV57487334; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRB1 | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 64/339 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs267598278, COSV66329373; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.6562C>T p.R2188* | Nonsense Mutation (SNP) | VAF 52/407 reads (13%) | catalogued as rs200497972, COSV63281417; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYCN | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 76/453 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057517770, COSV55258811; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PCSK9 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 49/450 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs793888521, CM164687; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- UROC1 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 91/373 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852795, CM093242; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.109); catalogued as rs1464862721; called by muse, mutect2, varscan2
- A2ML1 | c.871T>C p.C291R | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1310248691; called by muse, mutect2, varscan2
- ABCA13 | c.12962C>T p.S4321L | Missense Mutation (SNP) | VAF 39/386 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV68946248; called by muse, mutect2, varscan2
- ABCA4 | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 248/596 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs770774620; called by muse, varscan2
- ABCB1 | c.3517G>A p.G1173R | Missense Mutation (SNP) | VAF 133/342 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473237773; called by muse, mutect2, varscan2
- ABCB1 | c.2702T>A p.I901K | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55952788; called by muse, mutect2, varscan2
- ABCC9 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.495); catalogued as rs143685061; ClinVar: uncertain significance; called by muse, varscan2
- ABI3BP | c.2153A>T p.N718I | Missense Mutation (SNP) | VAF 85/374 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV52554053; called by muse, mutect2, varscan2
- ABRAXAS2 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs765356910, COSV100045102; called by muse, mutect2, varscan2
- AC126283.2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773085612, CM161603, COSV67098504; called by muse, mutect2, varscan2
- ACACB | c.2390C>T p.S797F | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV100623287; called by muse, mutect2, varscan2
- ACACB | c.2821C>T p.R941W | Missense Mutation (SNP) | VAF 65/318 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.846); catalogued as rs780115048; called by muse, mutect2, varscan2
- ACAD11 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53896160; called by muse, mutect2, varscan2
- ACAD11 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV53894922; called by muse, mutect2, varscan2
- ACAN | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 168/350 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV61356492; called by muse, mutect2, varscan2
- ACAN | c.4655G>A p.G1552E | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.219); catalogued as COSV61369171; called by muse, mutect2, varscan2
- ACD | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 184/561 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.013); catalogued as COSV54665920, COSV99538042; called by muse, mutect2, varscan2
- ACKR1 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 100/306 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); catalogued as COSV63674515; called by muse, mutect2, varscan2
- ACMSD | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 155/465 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598885, COSV51606002, COSV51609903; called by muse, mutect2, varscan2
- ACSL3 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 42/423 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs776538313, COSV62481117; called by muse, mutect2, varscan2
- ACSL5 | c.407G>A p.G136D (on ENST00000354273; = p.G192D on NM_016234.3) | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866014176; called by muse, varscan2
- ACTR3B | c.225G>A p.K75= | Splice Region (SNP) | VAF 41/201 reads (20%) | catalogued as COSV55450043; called by muse, mutect2, varscan2
- ADAD2 | c.1636G>A p.E546K (on ENST00000315906 / NM_001145400.2; = p.E628K on NM_139174.4) | Missense Mutation (SNP) | VAF 80/396 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as rs914904996, COSV51894041; called by muse, mutect2, varscan2
- ADAM18 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.031); catalogued as COSV55847632; called by muse, mutect2, varscan2
- ADAM29 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 122/423 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs376197978; called by muse, mutect2, varscan2
- ADAM7 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.04); catalogued as rs768627416, COSV51537798; called by muse, mutect2, varscan2
- ADAM7 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 71/368 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61757471, COSV51536147; called by muse, mutect2, varscan2
- ADAMTS18 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 53/378 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs751194192, COSV99274405; called by muse, mutect2, varscan2
- ADAMTS9 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 61/324 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.076); catalogued as rs773453319, COSV55790673; called by muse, mutect2, varscan2
- ADAMTS9 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55777721, COSV99899601; called by muse, mutect2, varscan2
- ADAMTSL1 | c.5130G>A p.W1710* | Nonsense Mutation (SNP) | VAF 171/444 reads (39%) | catalogued as rs760817930; called by muse, mutect2, varscan2
- ADAMTSL1 | c.5131G>A p.G1711R | Missense Mutation (SNP) | VAF 170/442 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1322321479; called by muse, mutect2, varscan2
- ADCY5 | c.3072G>T p.E1024D | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as COSV59204504; called by muse, mutect2, varscan2
- ADCY5 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 135/537 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.187); catalogued as rs1023838544; called by muse, mutect2, varscan2
- ADGRD1 | c.2518C>T p.H840Y | Missense Mutation (SNP) | VAF 56/350 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as rs1253655764; called by muse, mutect2
- ADGRL2 | c.4058C>T p.S1353F (on ENST00000370717 / NM_001366005.1; = p.S1297F on NM_012302.4) | Missense Mutation (SNP) | VAF 49/481 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV54698050, COSV99046898; called by muse, mutect2, varscan2
- ADGRL3 | c.1120G>A p.D374N (on ENST00000506720 / NM_001322402.2; = p.D306N on NM_015236.6) | Missense Mutation (SNP) | VAF 72/362 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV72269560; called by muse, mutect2, varscan2
- ADGRL3 | c.2497G>A p.G833R (on ENST00000506720 / NM_001322402.2; = p.G765R on NM_015236.6) | Missense Mutation (SNP) | VAF 45/601 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs1249372998; called by muse, mutect2
- ADGRL4 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 40/454 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66063769; called by muse, mutect2
- ADH5 | c.114+1G>A p.X38_splice | Splice Site (SNP) | VAF 68/299 reads (23%) | catalogued as rs370062163; called by muse, mutect2, varscan2
- ADRA2A | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 215/582 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV99701897; called by muse, mutect2, varscan2
- AGAP4 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV101432615; called by muse, mutect2, varscan2
- AGO4 | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 64/383 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1006671149, COSV100942857; called by muse, mutect2, varscan2
- AHNAK | c.12761C>T p.A4254V | Missense Mutation (SNP) | VAF 43/455 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV99945871; called by muse, mutect2, varscan2
- AHNAK2 | c.13049C>T p.P4350L | Missense Mutation (SNP) | VAF 63/372 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.022); catalogued as rs775570955; called by muse, mutect2, varscan2
- AHNAK2 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 108/532 reads (20%) | catalogued as rs1188646569, COSV60912557; called by muse, varscan2
- AHSP | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 139/423 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV56528664; called by muse, mutect2, varscan2
- AKAIN1 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs1189292467; called by muse, mutect2, varscan2
- AKAP3 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1345037350, COSV57420026; called by muse, mutect2, varscan2
- AKNA | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 131/479 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV56337188; called by muse, mutect2, varscan2
- AL592490.1 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101308241; called by muse, mutect2, varscan2
- AL592490.1 | c.785A>G p.E262G | Missense Mutation (SNP) | VAF 72/403 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs751267885, COSV69427512; called by muse, mutect2, varscan2
- AL592490.1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 72/398 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV69426761; called by muse, mutect2, varscan2
- ALB | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs774294755, COSV55738750, COSV55739357; called by muse, mutect2, varscan2
- ALDH1L1 | c.897G>A p.M299I | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.692); catalogued as COSV56412707; called by muse, mutect2, varscan2
- ALG8 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 43/422 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748962880, CM098505; called by muse, mutect2
- ALOX12B | c.229T>G p.F77V | Missense Mutation (SNP) | VAF 52/372 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.175); catalogued as COSV59871393; called by muse, mutect2, varscan2
- ALS2 | c.4270C>T p.Q1424* | Nonsense Mutation (SNP) | VAF 82/279 reads (29%) | catalogued as COSV51885932, COSV51888690; called by muse, mutect2, varscan2
- AMY1C | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 32/663 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1203608595; called by muse, mutect2
- ANGEL1 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 134/445 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546885277; called by muse, mutect2, varscan2
- ANHX | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 87/333 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV69293514, COSV69294039; called by muse, mutect2, varscan2
- ANK1 | c.4577C>T p.S1526F | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.581); catalogued as rs777979057; called by muse, mutect2, varscan2
- ANK2 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1327848108, COSV52183131; called by muse, mutect2, varscan2
- ANK3 | c.13130C>T p.S4377L (on ENST00000280772 / NM_001320874.2; = p.S1001L on NM_001149.3) | Missense Mutation (SNP) | VAF 147/346 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as rs201169886; called by muse, mutect2
- ANK3 | c.8686G>A p.E2896K | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV55073735; called by muse, mutect2, varscan2
- ANKEF1 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 46/378 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV65693696; called by muse, mutect2, varscan2
- ANKEF1 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 62/417 reads (15%) | catalogued as rs763362315; called by muse, mutect2, varscan2
- ANKRD11 | c.6164C>T p.P2055L | Missense Mutation (SNP) | VAF 86/568 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.348); catalogued as rs1281426768; called by muse, mutect2, varscan2
- ANKRD18A | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 68/350 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as rs528054598, COSV68803926; called by muse, mutect2, varscan2
- ANKRD30B | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV62813745; called by muse, mutect2, varscan2
- ANKRD33 | c.61C>T p.L21F (on ENST00000340970 / NM_001304459.2; = p.L156F on NM_182608.4) | Missense Mutation (SNP) | VAF 103/416 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1331722896; called by muse, mutect2, varscan2
- ANKRD35 | c.1554G>A p.M518I | Missense Mutation (SNP) | VAF 98/424 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs781970487, COSV100841732; called by muse, mutect2, varscan2
- ANKRD7 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54554663; called by muse, mutect2, varscan2
- ANO3 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 44/420 reads (10%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as COSV56805536; called by muse, mutect2
- ANO4 | c.2708C>T p.S903L (on ENST00000392977 / NM_001286615.2; = p.S868L on NM_178826.4) | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV54587306; called by muse, mutect2, varscan2
- ANO4 | c.2840G>A p.G947E (on ENST00000392977 / NM_001286615.2; = p.G912E on NM_178826.4) | Missense Mutation (SNP) | VAF 67/315 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.821); catalogued as COSV100153120; called by muse, mutect2, varscan2
- ANXA10 | c.63G>A p.M21I | Missense Mutation (SNP) | VAF 96/445 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV63740390; called by muse, mutect2, varscan2
- AP4E1 | c.2663C>T p.P888L | Missense Mutation (SNP) | VAF 165/371 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV99956779; called by muse, mutect2, varscan2
- APLF | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 85/499 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV58143985; called by muse, mutect2, varscan2
- APOB | c.10918C>T p.H3640Y | Missense Mutation (SNP) | VAF 91/493 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV51956078; called by muse, mutect2, varscan2
- APOB | c.3814C>T p.H1272Y | Missense Mutation (SNP) | VAF 155/379 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV51958098; called by muse, mutect2, varscan2
- APOL5 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 101/531 reads (19%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs768415716, COSV50766598; called by muse, mutect2, varscan2
- APOL6 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 98/513 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV101291015; called by muse, mutect2, varscan2
- APOOL | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 81/198 reads (41%) | catalogued as rs1166452268; called by muse, mutect2, varscan2
- ARAP2 | c.3074A>T p.D1025V | Missense Mutation (SNP) | VAF 103/422 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1206789876; called by muse, mutect2, varscan2
- ARAP2 | c.2999A>G p.K1000R | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1233247869; called by muse, mutect2, varscan2
- ARAP2 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 82/455 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.956); catalogued as COSV100394605, COSV58287024; called by muse, mutect2, varscan2
- ARFGEF3 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 78/325 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs375082443; called by muse, varscan2
- ARFGEF3 | c.3481G>A p.D1161N | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.194); catalogued as rs771752189, COSV52466521; called by muse, mutect2, varscan2
- ARHGAP21 | c.2527C>T p.P843S | Missense Mutation (SNP) | VAF 122/356 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV57612113; called by muse, mutect2, varscan2
- ARHGAP23 | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 49/416 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs1333070555; called by muse, mutect2, varscan2
- ARHGAP26 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50829120; called by muse, mutect2, varscan2
- ARHGAP32 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV59855612; called by muse, mutect2, varscan2
- ARHGEF17 | c.4651C>T p.L1551F | Missense Mutation (SNP) | VAF 73/541 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1415397584; called by muse, mutect2, varscan2
- ARHGEF7 | c.1791C>T p.L597= (on ENST00000375741 / NM_001113511.2; = p.L419= on NM_003899.5 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 71/449 reads (16%) | catalogued as rs1164951891; called by muse, mutect2, varscan2
- ARID1B | c.3099G>A p.K1033= | Splice Region (SNP) | VAF 44/207 reads (21%) | catalogued as rs373653398; called by muse, mutect2, varscan2
- ARID2 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 53/292 reads (18%) | catalogued as rs994352749; called by muse, mutect2, varscan2
- ARID5B | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 142/384 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV54430683; called by muse, mutect2, varscan2
- ARMC2 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 124/461 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs138386250; called by muse, mutect2, varscan2
- ARRDC5 | c.593C>T p.T198I (on ENST00000381781; = p.T184I on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/413 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV67788344; called by muse, mutect2, varscan2
- ARSH | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as rs759497002, COSV66962565; called by muse, mutect2, varscan2
- ASB17 | c.47G>A p.S16N | Missense Mutation (SNP) | VAF 27/272 reads (10%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.162); catalogued as COSV52412040; called by muse, mutect2, varscan2
- ASH2L | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 82/603 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.013); catalogued as rs1401405242; called by muse, mutect2, varscan2
- ASIC4 | c.451C>A p.R151S | Missense Mutation (SNP) | VAF 110/676 reads (16%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.742); catalogued as rs771952448, COSV61731676; called by muse, mutect2, varscan2
- ASTN1 | c.3623G>A p.R1208Q | Missense Mutation (SNP) | VAF 107/278 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768973979, COSV62496507; called by muse, mutect2, varscan2
- ASTN1 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 68/288 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763391667, COSV56064196; called by muse, varscan2
- ATF6B | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 99/461 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV64351243; called by muse, mutect2, varscan2
- ATM | c.8978G>A p.R2993Q | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs587778081, CX002572, COSV53733041; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- ATN1 | c.2486_2503del p.R829_E834del | In Frame Del (DEL) | VAF 55/314 reads (18%) | catalogued as rs1367398901; called by mutect2, varscan2
- ATP10A | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.072); catalogued as rs1385055394, COSV63526525; called by muse, mutect2
- ATP13A2 | c.2336C>T p.T779I | Missense Mutation (SNP) | VAF 92/727 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs1231659616; called by muse, mutect2
- ATP1A4 | c.2750G>A p.R917Q | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs764509935; called by muse, mutect2, varscan2
- ATP2A1 | c.2183A>G p.K728R | Missense Mutation (SNP) | VAF 72/392 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs747116287; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A3 | c.2171C>A p.T724K | Missense Mutation (SNP) | VAF 160/381 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99989038; called by muse, mutect2, varscan2
- ATP2A3 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 100/511 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV59234488; called by muse, mutect2, varscan2
- ATP2B2 | c.2266C>T p.R756C (on ENST00000352432; = p.R722C on NM_001683.5) | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs762199117, COSV100660016; called by muse, varscan2
- ATP2C2 | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV52293969; called by muse, mutect2, varscan2
- ATP8A1 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 99/319 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs267600160, COSV52529896; called by muse, mutect2, varscan2
- ATRNL1 | c.3728C>T p.S1243F | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100371101, COSV58089242; called by muse, mutect2, varscan2
- B3GAT2 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1367932495; called by muse, mutect2, varscan2
- B3GNT8 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 82/573 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs769165524; called by muse, mutect2, varscan2
- BAHCC1 | c.3835C>T p.P1279S | Missense Mutation (SNP) | VAF 103/726 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV57027066; called by muse, mutect2, varscan2
- BARD1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 76/453 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs758368819, COSV53611819; called by muse, mutect2, varscan2
- BCAR1 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 92/675 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs751244629; called by muse, mutect2, varscan2
- BCL11A | c.1885T>C p.Y629H (on ENST00000335712 / NM_001365609.1; = p.Y663H on NM_018014.4) | Missense Mutation (SNP) | VAF 91/635 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1227579541; called by muse, mutect2, varscan2
- BCORL1 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 166/740 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.725); catalogued as rs754043220; called by muse, varscan2
- BCR | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 180/490 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs1337299573, COSV59928527; called by muse, mutect2, varscan2
- BEST3 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748231464, COSV56994383; called by muse, varscan2
- BMPER | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.383); catalogued as rs1228099396, COSV51814331; called by muse, mutect2, varscan2
- BNIPL | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs201384045, COSV54848559; called by muse, mutect2, varscan2
- BPIFB2 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 93/572 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401755; called by muse, mutect2, varscan2
- BPIFB4 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 117/341 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.878); catalogued as rs535736291, COSV64951283; called by muse, mutect2, varscan2
- BRCA2 | c.6628G>A p.E2210K | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV66451327; called by muse, mutect2, varscan2
- BRD2 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 88/409 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.695); catalogued as COSV66373056; called by muse, mutect2, varscan2
- BRDT | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs760550779, COSV62866557; called by muse, mutect2, varscan2
- BRINP3 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 135/357 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.147); catalogued as rs375567534, COSV66538726; called by muse, varscan2
- C11orf95 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 93/600 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1244411958; called by muse, mutect2, varscan2
- C12orf50 | c.505A>G p.K169E | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100072436; called by muse, mutect2, varscan2
- C14orf180 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100118822, COSV99045674; called by muse, mutect2, varscan2
- C1QTNF9 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217238221; called by mutect2, varscan2
- C1S | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.37); catalogued as COSV100196394; called by muse, mutect2, varscan2
- C1orf115 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 81/248 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs763806580; called by muse, mutect2, varscan2
- C1orf162 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 49/388 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.234); catalogued as COSV100636254; called by muse, mutect2, varscan2
- C20orf203 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 92/509 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs912334584; called by muse, mutect2, varscan2
- C2orf80 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 78/378 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV58017201; called by muse, mutect2, varscan2
- C3orf20 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 60/287 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as COSV104389297; called by muse, mutect2, varscan2
- C6orf15 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 134/600 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV99456658; called by mutect2, varscan2
- C7orf61 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 192/504 reads (38%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1433498181; called by muse, mutect2, varscan2
- C9 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767572697; called by muse, mutect2, varscan2
- CACNA1B | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 105/224 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1294351388; called by muse, varscan2
- CACNA1B | c.6872C>T p.S2291F | Missense Mutation (SNP) | VAF 139/611 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs1222036403, COSV53123101; called by muse, mutect2, varscan2
- CACNA1C | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 112/498 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs1027539784, COSV59702441; called by muse, mutect2, varscan2
- CACNA1E | c.2933C>T p.A978V | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV62405524, COSV62408644; called by muse, mutect2, varscan2
- CACNA1H | c.6188G>A p.R2063Q | Missense Mutation (SNP) | VAF 199/637 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs866288176, COSV52353044; called by muse, mutect2, varscan2
- CADPS | c.3742G>A p.V1248I | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs751860249, COSV99340661; called by muse, mutect2, varscan2
- CADPS | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 59/299 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as COSV99338789; called by muse, mutect2, varscan2
- CADPS2 | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.74); catalogued as rs867582496; called by muse, mutect2
- CAMSAP3 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 255/645 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs1384777444; called by muse, mutect2, varscan2
- CAPN14 | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs1176667390; called by muse, mutect2
- CAPN8 | c.1891A>G p.R631G | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1187698743; called by muse, mutect2
- CARD18 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 73/409 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.326); catalogued as COSV101596041; called by muse, mutect2, varscan2
- CBL | c.1096-1G>A p.X366_splice | Splice Site (SNP) | VAF 41/143 reads (29%) | catalogued as CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; called by muse, mutect2, varscan2
- CBL | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1245863855, COSV50657369, COSV50665310; called by muse, mutect2, varscan2
- CCDC110 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.769); catalogued as COSV100294059, COSV56869319; called by muse, mutect2, varscan2
- CCDC141 | c.2912C>T p.S971F | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV55369638; called by muse, mutect2, varscan2
- CCDC141 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 83/478 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs769268802, COSV55371354; called by muse, mutect2, varscan2
- CCDC158 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 128/483 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs370067451; called by muse, mutect2, varscan2
- CCDC168 | c.16708A>T p.T5570S | Missense Mutation (SNP) | VAF 85/395 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV100487593; called by muse, mutect2, varscan2
- CCDC168 | c.12136G>A p.E4046K | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.281); catalogued as COSV59421924; called by muse, mutect2, varscan2
- CCDC175 | c.1352G>A p.R451K | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs1174365842, COSV55786932; called by muse, mutect2
- CCDC3 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV101121771, COSV66558838; called by muse, mutect2, varscan2
- CCDC68 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV61604679; called by muse, mutect2, varscan2
- CCDC88B | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 104/495 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.559); catalogued as rs970377728; called by muse, mutect2, varscan2
- CCL26 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 113/348 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs782727471; called by muse, mutect2, varscan2
- CCNB3 | c.2030C>T p.S677L | Missense Mutation (SNP) | VAF 66/375 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV99329927; called by muse, mutect2, varscan2
- CCNT1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 27/426 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV56065201; called by muse, mutect2
- CCR2 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 73/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52750465; called by muse, mutect2, varscan2
- CD109 | c.3650C>T p.P1217L | Missense Mutation (SNP) | VAF 73/360 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV99754282; called by muse, mutect2, varscan2
- CD164 | c.330C>T p.S110= | Splice Region (SNP) | VAF 36/230 reads (16%) | catalogued as rs199887608; ClinVar: likely benign; called by muse, mutect2, varscan2
- CD200R1L | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68004516; called by muse, mutect2, varscan2
- CD276 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.289); catalogued as rs1320456567; called by muse, mutect2, varscan2
- CD300E | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 94/484 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs1250703050, COSV60791455; called by muse, mutect2, varscan2
- CD33 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 142/542 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs267605607, COSV99220764; called by muse, mutect2, varscan2
- CD40 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs1406703700; called by muse, mutect2, varscan2
- CDH12 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 101/272 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66390362; called by muse, mutect2, varscan2
- CDH12 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs945820536, COSV101200656, COSV66455223; called by muse, mutect2, varscan2
- CDH17 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 64/297 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs868699389; called by muse, mutect2, varscan2
- CDH8 | c.2077G>A p.G693R | Missense Mutation (SNP) | VAF 67/507 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.105); catalogued as rs867793640, COSV54905377; called by muse, mutect2, varscan2
- CDON | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 65/402 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs758713160; called by muse, mutect2, varscan2
- CDRT1 | c.1233G>A p.T411= | Splice Region (SNP) | VAF 11/86 reads (13%) | catalogued as rs1334458042; called by muse, mutect2, varscan2
- CEACAM20 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 112/342 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57601775; called by muse, mutect2, varscan2
- CEACAM8 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 93/333 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.424); catalogued as rs985625692, COSV99747478; called by muse, mutect2, varscan2
- CELSR1 | c.6115C>T p.P2039S | Missense Mutation (SNP) | VAF 165/449 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs753225249; called by muse, mutect2, varscan2
- CELSR2 | c.4333G>A p.G1445R | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs753290065, COSV54775550; called by muse, mutect2, varscan2
- CERS6 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 84/418 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV59836181; called by muse, mutect2, varscan2
- CES3 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1292970444; called by muse, varscan2
- CETN2 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs782779595, COSV64743193; called by muse, varscan2
- CFAP43 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 88/326 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs750966857; called by muse, mutect2, varscan2
- CFAP54 | c.5975G>A p.G1992E | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1478385976; called by muse, mutect2, varscan2
- CFAP65 | c.4639G>A p.E1547K | Missense Mutation (SNP) | VAF 63/441 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs1172470608; called by muse, mutect2, varscan2
- CFAP65 | c.3166C>T p.P1056S | Missense Mutation (SNP) | VAF 80/497 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as COSV58563788; called by muse, mutect2, varscan2
- CFHR4 | c.1591G>A p.G531R (on ENST00000367416 / NM_001201551.2; = p.G285R on NM_006684.5) | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.482); catalogued as COSV52226308; called by muse, mutect2, varscan2
- CFP | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 96/457 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as COSV55950992; called by muse, mutect2, varscan2
- CGNL1 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs770839772; called by muse, mutect2, varscan2
- CHRNA1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 167/501 reads (33%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs146743352, COSV53682258; called by muse, mutect2, varscan2
- CHRNA2 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 86/372 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.773); catalogued as rs774054592, COSV53557297; called by muse, mutect2, varscan2
- CHRNA6 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as rs772665574; called by muse, mutect2, varscan2
- CIC | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 167/586 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.268); catalogued as COSV50568090, COSV99360207; called by muse, mutect2, varscan2
- CIC | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 126/403 reads (31%) | catalogued as COSV50548132; called by muse, mutect2, varscan2
- CLASP1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 157/421 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746501087, COSV55321894; called by muse, mutect2, varscan2
- CLCN2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 58/281 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs752010877; called by muse, mutect2, varscan2
- CLDN14 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59775955; called by muse, mutect2
- CLDN18 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 59/327 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs768414784, COSV51738820; called by muse, mutect2, varscan2
- CLEC6A | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.066); catalogued as COSV65987455; called by muse, mutect2, varscan2
- CLIP4 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 109/326 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as COSV60750830; called by muse, mutect2, varscan2
- CLSTN2 | c.2083G>C p.D695H | Missense Mutation (SNP) | VAF 39/317 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1329618210, COSV71718337; called by muse, mutect2, varscan2
- CMAS | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs372322273; called by muse, mutect2, varscan2
- CMYA5 | c.4711C>T p.P1571S | Missense Mutation (SNP) | VAF 55/356 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV71410414; called by muse, mutect2, varscan2
- CNGB3 | c.2201G>A p.G734E | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs757799031, COSV60686027, COSV60687783; called by muse, mutect2, varscan2
- CNPY1 | c.64G>A p.E22K (on ENST00000636446; = p.E3K on NM_001369813.1) | Missense Mutation (SNP) | VAF 39/374 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1368450100; called by muse, mutect2, varscan2
- CNTN5 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 52/410 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.345); catalogued as rs1317730113, COSV54355612; called by muse, mutect2, varscan2
- CNTN5 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54285866; called by muse, mutect2, varscan2
- CNTNAP2 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 70/406 reads (17%) | catalogued as COSV62156912; called by muse, mutect2, varscan2
- COL11A1 | c.3254C>T p.P1085L | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62179994; called by muse, mutect2, varscan2
- COL14A1 | c.3919G>A p.E1307K | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52847444; called by muse, mutect2, varscan2
- COL1A1 | c.3574C>T p.P1192S | Missense Mutation (SNP) | VAF 89/646 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1475743388, COSV56805031; called by muse, mutect2, varscan2
- COL1A2 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 33/396 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755058199, COSV51954646; called by muse, mutect2
- COL1A2 | c.2324G>A p.G775E | Missense Mutation (SNP) | VAF 149/427 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51957336; called by muse, mutect2, varscan2
- COL21A1 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55155492; called by muse, mutect2, varscan2
- COL21A1 | c.1013A>G p.N338S | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV55172173; called by muse, mutect2, varscan2
- COL22A1 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 61/291 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); catalogued as rs778667471, COSV57325080; called by muse, varscan2
- COL27A1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV61927749; called by muse, mutect2, varscan2
- COL4A3 | c.3864G>A p.M1288I | Missense Mutation (SNP) | VAF 109/353 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59258193; called by muse, mutect2, varscan2
- COL4A4 | c.3665C>T p.P1222L | Missense Mutation (SNP) | VAF 78/488 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs377230950; called by muse, mutect2, varscan2
- COL4A5 | c.3266G>A p.G1089E | Missense Mutation (SNP) | VAF 75/335 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM115545; called by muse, mutect2, varscan2
- COL5A1 | c.2350G>A p.G784S | Missense Mutation (SNP) | VAF 144/377 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767627080, COSV100880585; called by muse, mutect2, varscan2
- COL5A2 | c.2608G>A p.G870R | Missense Mutation (SNP) | VAF 64/353 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66413060; called by muse, mutect2, varscan2
- COL6A1 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 40/442 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.07); catalogued as rs1483485124; called by muse, mutect2
- COL6A3 | c.8021C>T p.S2674F | Missense Mutation (SNP) | VAF 261/577 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.339); catalogued as rs1169456064, COSV55110075; called by muse, mutect2, varscan2
- COL6A3 | c.6460C>T p.R2154* | Nonsense Mutation (SNP) | VAF 56/406 reads (14%) | catalogued as rs762768377, COSV104402597, COSV55079291; called by muse, mutect2, varscan2
- COL6A3 | c.4649G>A p.G1550E | Missense Mutation (SNP) | VAF 308/671 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV55078348; called by muse, mutect2, varscan2
- COL6A5 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 76/380 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs976274616, COSV55208289; called by muse, mutect2, varscan2
- COL7A1 | c.8776G>A p.E2926K | Missense Mutation (SNP) | VAF 106/566 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV56476438; called by muse, mutect2, varscan2
- COL8A2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 72/610 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.646); catalogued as rs776813844, COSV57442924; called by muse, mutect2, varscan2
- COL9A1 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 67/258 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753682260, COSV100294120, COSV57893257; called by muse, mutect2, varscan2
- COLEC10 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1215289749; called by muse, mutect2, varscan2
- COMMD6 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.416); catalogued as COSV100869867; called by muse, mutect2, varscan2
- COMMD8 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 92/481 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.978); catalogued as rs1466358636, COSV67500322; called by muse, mutect2, varscan2
- COPS7A | c.655A>C p.T219P | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV57527080; called by muse, mutect2, varscan2
- CPA3 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as rs1458791547; called by muse, mutect2, varscan2
- CPN1 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 78/292 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs908037906, COSV64941879; called by muse, mutect2, varscan2
- CPXM2 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 80/618 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs1217291885, COSV53867392; called by muse, mutect2, varscan2
- CR2 | c.2606G>A p.R869Q | Missense Mutation (SNP) | VAF 103/294 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.188); catalogued as rs756989345, COSV100889697; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRYBG1 | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.02); catalogued as COSV64814026; called by muse, mutect2, varscan2
- CRYBG1 | c.5966G>A p.R1989Q | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs753275483, COSV64811380; called by muse, mutect2, varscan2
- CSMD1 | c.10370G>A p.G3457E (on ENST00000520002; = p.G3456E on NM_033225.6) | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV59301362; called by muse, mutect2
- CSMD1 | c.6371C>T p.P2124L (on ENST00000520002; = p.P2123L on NM_033225.6) | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59293363; called by muse, mutect2, varscan2
- CSMD1 | c.5612G>A p.G1871E (on ENST00000520002; = p.G1870E on NM_033225.6) | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761601416, COSV59299434; called by muse, mutect2, varscan2
- CSMD1 | c.3142G>A p.D1048N (on ENST00000520002; = p.D1047N on NM_033225.6) | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59282193; called by muse, mutect2, varscan2
- CSMD1 | c.3089C>T p.S1030L (on ENST00000520002; = p.S1029L on NM_033225.6) | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773842728, COSV59282220; called by muse, mutect2, varscan2
- CSMD1 | c.2329G>A p.G777R (on ENST00000520002; = p.G776R on NM_033225.6) | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1184130564; called by muse, mutect2, varscan2
- CSMD2 | c.9232C>T p.R3078C | Missense Mutation (SNP) | VAF 127/330 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1283736318, COSV53915658, COSV53961019; called by muse, mutect2, varscan2
- CSMD2 | c.6764G>A p.S2255N | Missense Mutation (SNP) | VAF 53/601 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs201941971; called by muse, mutect2
- CSMD2 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 55/322 reads (17%) | catalogued as rs775939532, COSV53891554; called by muse, mutect2, varscan2
- CSMD3 | c.9172G>A p.D3058N (on ENST00000297405 / NM_001363185.1; = p.D2889N on NM_052900.3) | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.443); catalogued as rs759864023, COSV52105606, COSV52257196; called by muse, varscan2
- CSN2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 187/535 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.462); catalogued as rs753388171; called by muse, mutect2, varscan2
- CTAGE1 | c.1544G>A p.R515K | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1308824372; called by muse, mutect2, varscan2
- CTAGE15 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs757722933, COSV69481949; called by muse, mutect2, varscan2
- CTAGE8 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV100966767; called by muse, mutect2, varscan2
- CTAGE9 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 46/358 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs1430254029, COSV100020665; called by muse, mutect2, varscan2
- CUL4A | c.1768C>T p.Q590* (on ENST00000375440 / NM_001008895.4; = p.Q490* on NM_003589.3) | Nonsense Mutation (SNP) | VAF 31/223 reads (14%) | catalogued as COSV58376449; called by muse, mutect2, varscan2
- CXCR5 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 73/586 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs149961413; called by muse, mutect2, varscan2
- CYP1A2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 81/377 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1389226935; called by muse, mutect2, varscan2
- CYP2C18 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.341); catalogued as COSV53670127; called by muse, mutect2, varscan2
- CYP2C19 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 113/317 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV64909219; called by muse, mutect2, varscan2
- CYP2C8 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as CM115008, COSV64878951; called by muse, varscan2
- CYP2F1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 116/419 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs747690814; called by muse, mutect2, varscan2
- CYP3A7 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220927730, COSV60480780; called by muse, mutect2
- DAAM2 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV51373392; called by muse, mutect2, varscan2
- DACH1 | c.1720G>A p.E574K (on ENST00000619232 / NM_001366712.1; = p.E522K on NM_080759.6) | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV57498706, COSV57499795; called by muse, varscan2
- DAGLA | c.677T>A p.F226Y | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1199338512; called by muse, mutect2
- DBH | c.1808G>A p.S603N | Missense Mutation (SNP) | VAF 81/417 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.107); catalogued as rs1200124192; called by muse, mutect2, varscan2
- DCAF4L2 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 98/347 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs868106740, COSV60477762, COSV60480991; called by muse, mutect2, varscan2
- DCAF5 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 76/525 reads (14%) | catalogued as COSV58459615; called by muse, mutect2, varscan2
- DCC | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 66/302 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs191508830; called by muse, mutect2, varscan2
- DDHD2 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs754907740; called by muse, mutect2, varscan2
- DDIAS | c.2620C>T p.P874S | Missense Mutation (SNP) | VAF 104/331 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.073); catalogued as rs1481559101, COSV61273578; called by muse, mutect2, varscan2
- DDX25 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs373696148; called by muse, mutect2, varscan2
- DDX51 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 82/342 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs1192145074, COSV57957539; called by muse, mutect2, varscan2
- DENND1B | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 103/253 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753673713; called by muse, mutect2, varscan2
- DENND2A | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 86/320 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52060421; called by muse, mutect2, varscan2
- DENND3 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 141/502 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52802920; called by muse, mutect2, varscan2
- DHRS4 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 79/329 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs772524465, COSV57481451; called by muse, varscan2
- DHRS9 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 174/505 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs749731465; called by muse, mutect2, varscan2
- DIABLO | c.320C>T p.S107F (on ENST00000443649 / NM_001278303.1; = p.S180F on NM_019887.6) | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767109973; called by muse, mutect2, varscan2
- DIO3 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 141/667 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63773286; called by muse, varscan2
- DIP2B | c.2482A>G p.I828V | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs562083624; called by muse, mutect2, varscan2
- DISP3 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 286/688 reads (42%) | catalogued as rs781482486, COSV53822569; called by muse, mutect2, varscan2
- DISP3 | c.3814G>A p.E1272K | Missense Mutation (SNP) | VAF 88/397 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as rs774307670, COSV53834694; called by muse, mutect2, varscan2
- DLEC1 | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs777861082; called by muse, mutect2, varscan2
- DMBX1 | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 326/811 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs758576876; called by muse, mutect2, varscan2
- DMC1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201014421, COSV53258054; called by muse, mutect2, varscan2
- DMD | c.8188G>A p.G2730R | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as COSV58891776; called by muse, mutect2, varscan2
- DMRT2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 166/743 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as rs866098197; called by muse, mutect2, varscan2
- DNAAF5 | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 109/573 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV52416339; called by muse, mutect2, varscan2
- DNAH10 | c.1018G>A p.E340K (on ENST00000409039; = p.E279K on NM_207437.3) | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69000080; called by muse, mutect2, varscan2
- DNAH10 | c.7870C>T p.R2624* (on ENST00000409039; = p.R2563* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 149/614 reads (24%) | catalogued as rs1021332828, COSV101292108; called by muse, mutect2, varscan2
- DNAH11 | c.9212C>T p.P3071L | Missense Mutation (SNP) | VAF 42/543 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1216148023; called by muse, mutect2
- DNAH12 | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as rs775309505; called by muse, mutect2, varscan2
- DNAH12 | c.1690C>G p.L564V | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV61065714; called by muse, mutect2, varscan2
- DNAH12 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1006370903, COSV60855640, COSV60856070; called by muse, mutect2, varscan2
- DNAH14 | c.8846-1G>A p.X2949_splice | Splice Site (SNP) | VAF 29/190 reads (15%) | catalogued as rs1163826712; called by muse, mutect2, varscan2
- DNAH14 | c.9700G>A p.E3234K (on ENST00000445597; = p.E4242K on NM_001367479.1) | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); catalogued as COSV59900784; called by muse, mutect2, varscan2
- DNAH2 | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 92/350 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV101209368; called by muse, mutect2, varscan2
- DNAH3 | c.6371G>A p.R2124Q | Missense Mutation (SNP) | VAF 117/341 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776382752, COSV54515852; called by muse, mutect2, varscan2
- DNAH6 | c.10343G>A p.G3448E | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV52877167; called by muse, mutect2, varscan2
- DNAH7 | c.10760C>T p.A3587V | Missense Mutation (SNP) | VAF 118/323 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56788953; called by muse, mutect2, varscan2
- DNAH8 | c.11195G>A p.R3732K | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59426940; called by muse, mutect2, varscan2
- DNAJC13 | c.3205C>T p.R1069W | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53445460; called by muse, mutect2, varscan2
- DNAJC16 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 42/359 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as rs765366404; called by muse, mutect2, varscan2
- DOCK9 | c.506C>T p.S169F (on ENST00000376460 / NM_001366676.2; = p.S170F on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs201914404; called by muse, mutect2, varscan2
- DOT1L | c.2770G>A p.G924S | Missense Mutation (SNP) | VAF 46/386 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs1212427702; called by muse, varscan2
- DRC7 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs763592940, COSV61054724; called by muse, mutect2
- DSCAM | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs369442382, COSV101260693; called by muse, mutect2
- DSE | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 85/380 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100528597; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 57/320 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as rs769670477, COSV50050996; called by muse, mutect2, varscan2
- DUXA | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 59/384 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs958200676; called by muse, mutect2, varscan2
- DVL3 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 99/538 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); catalogued as rs770741192; called by muse, mutect2, varscan2
- DYSF | c.5318C>T p.P1773L | Missense Mutation (SNP) | VAF 84/536 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV50302694; called by muse, mutect2, varscan2
- EBF1 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.313); catalogued as rs775664953, COSV100565913; called by muse, mutect2, varscan2
- EBF2 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 68/335 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.184); catalogued as COSV68775882; called by muse, mutect2, varscan2
- ECE1 | c.139-6C>T | Splice Region (SNP) | VAF 79/701 reads (11%) | catalogued as rs1001128787; called by muse, mutect2, varscan2
- EFCAB6 | c.3260G>A p.G1087E | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs781531325; called by muse, varscan2
- EIF4G3 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.067); catalogued as COSV51681367; called by muse, mutect2, varscan2
- ELAVL4 | c.100C>G p.P34A | Missense Mutation (SNP) | VAF 92/449 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV63915506; called by muse, mutect2, varscan2
- EML2 | c.62_78del p.A21Gfs*33 | Frame Shift Del (DEL) | VAF 234/916 reads (26%) | catalogued as rs1205020984; called by mutect2, varscan2
- EML5 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 80/413 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs375543692; called by muse, mutect2, varscan2
- ENPP1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs201300555; called by muse, mutect2, varscan2
- ENTPD4 | c.1154A>G p.Y385C | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs1200293083; called by muse, mutect2, varscan2
- EP400 | c.6877C>T p.R2293C | Missense Mutation (SNP) | VAF 64/289 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433414794, COSV57763285; called by muse, mutect2, varscan2
- EPB41L2 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs267600809; called by muse, varscan2
- EPHA6 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 61/318 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67576033; called by muse, mutect2, varscan2
- EPHB6 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 87/624 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1234796491, COSV63891356, COSV63891416; called by muse, mutect2, varscan2
- EPHB6 | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 87/588 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV63892370; called by muse, mutect2, varscan2
- ERC2 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 73/364 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV55626230; called by muse, varscan2
- EVPL | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 172/340 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs1483766206; called by muse, mutect2, varscan2
- EXOC3L2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 97/812 reads (12%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.497); catalogued as rs1293953135; called by muse, mutect2, varscan2
- EZH1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 47/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101331434; called by muse, mutect2, varscan2
- F11 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV53008558; called by muse, mutect2, varscan2
- F5 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 114/330 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as rs778572956; called by muse, mutect2, varscan2
- FAIM2 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs746490841; called by muse, mutect2, varscan2
- FAM135B | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV99420005; called by muse, mutect2, varscan2
- FAM160A2 | c.1775C>T p.T592I (on ENST00000449352 / NM_001098794.2; = p.T606I on NM_032127.4) | Missense Mutation (SNP) | VAF 174/540 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.22); catalogued as rs748524729; called by muse, mutect2, varscan2
- FAM163B | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 234/505 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs1485367084; called by muse, mutect2, varscan2
- FAM170B | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 58/501 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs866574926, COSV61253270; called by muse, mutect2, varscan2
- FAM170B | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 49/370 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV61253742; called by muse, mutect2, varscan2
- FAM171A2 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 194/502 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs879328636; called by muse, mutect2, varscan2
- FAM171B | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 95/329 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59002747; called by muse, mutect2, varscan2
- FAM186B | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as rs753838024; called by muse, mutect2, varscan2
- FAM216B | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs531732949; called by muse, mutect2, varscan2
- FAM222A | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 103/477 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.244); catalogued as COSV62722977, COSV62723032; called by muse, mutect2, varscan2
- FAM234A | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 98/377 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372571002; called by muse, mutect2, varscan2
- FAM3B | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 52/642 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs970237251, COSV63613053; called by muse, mutect2
- FAM47B | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 82/374 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV61454731; called by muse, mutect2, varscan2
- FAM47C | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 120/460 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.643); catalogued as COSV63723958; called by muse, varscan2
- FAM83H | c.3403C>T p.R1135C | Missense Mutation (SNP) | VAF 86/584 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs1272345829; called by muse, mutect2, varscan2
- FAR1 | c.1420C>T p.L474F | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs1383643580; called by muse, mutect2, varscan2
- FASN | c.4649C>T p.S1550L | Missense Mutation (SNP) | VAF 98/530 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as rs759056728, COSV100147801; called by muse, mutect2, varscan2
- FAT2 | c.5171C>T p.S1724L | Missense Mutation (SNP) | VAF 63/366 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs144779956; called by muse, mutect2, varscan2
- FAT4 | c.6568C>T p.R2190C | Missense Mutation (SNP) | VAF 82/370 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765922495, COSV100628797; called by muse, mutect2, varscan2
- FAT4 | c.8060G>A p.R2687Q | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs777764521, COSV58675395; called by muse, mutect2, varscan2
- FAT4 | c.9896G>A p.R3299H | Missense Mutation (SNP) | VAF 104/331 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs370611770, COSV58687349; called by muse, mutect2, varscan2
- FBXL4 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs1018430772; called by muse, mutect2, varscan2
- FBXO43 | c.2122C>T p.L708F | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751863250; called by muse, mutect2, varscan2
- FBXW10 | c.2383G>A p.G795R | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as rs762357073; called by muse, varscan2
- FCRL3 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.838); catalogued as COSV63840765, COSV63841174; called by muse, mutect2, varscan2
- FCRL5 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 88/476 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs890785912, COSV62510933; called by muse, mutect2, varscan2
- FER1L6 | c.3584C>T p.T1195I | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.307); catalogued as rs1468622183, COSV67550762; called by muse, mutect2, varscan2
- FGF11 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 130/319 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1341209409; called by muse, mutect2, varscan2
- FGF13 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 115/309 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101003642; called by muse, mutect2, varscan2
- FGF4 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 93/742 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1359046966; called by muse, mutect2, varscan2
- FGFR1 | c.1229G>A p.S410N (on ENST00000447712 / NM_023110.3; = p.S408N on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/321 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.073); catalogued as rs750688817; called by muse, mutect2, varscan2
- FHIT | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 55/318 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs769130211, COSV59286231, COSV59319274; called by muse, mutect2, varscan2
- FLG | c.7349C>T p.S2450F | Missense Mutation (SNP) | VAF 44/548 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs753498822; called by muse, mutect2
- FLG | c.4982C>T p.S1661F | Missense Mutation (SNP) | VAF 119/390 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1327217833; called by muse, mutect2, varscan2
- FLNA | c.6380G>A p.G2127D (on ENST00000369850 / NM_001110556.2; = p.G2119D on NM_001456.3) | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV100775341; called by muse, mutect2, varscan2
- FLNB | c.4745C>T p.P1582L | Missense Mutation (SNP) | VAF 67/367 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761987579; called by muse, varscan2
- FLNC | c.7408C>A p.P2470T | Missense Mutation (SNP) | VAF 63/379 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57952953; called by muse, mutect2, varscan2
- FLT3 | c.1977G>T p.M659I | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV54056547; called by muse, mutect2, varscan2
- FMO1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV61444890; called by muse, mutect2, varscan2
- FNBP4 | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1283641031; called by muse, mutect2, varscan2
- FNDC1 | c.2600C>T p.S867F | Missense Mutation (SNP) | VAF 98/423 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); catalogued as COSV99794652, COSV99796994; called by muse, mutect2, varscan2
- FNDC3A | c.2738del p.Y913Lfs*19 (on ENST00000492622 / NM_001079673.2; = p.Y857Lfs*19 on NM_014923.5) | Frame Shift Del (DEL) | VAF 87/332 reads (26%) | catalogued as COSV68133874; called by mutect2, pindel, varscan2
- FOLH1 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as rs763728006, COSV57048090; called by muse, mutect2, varscan2
- FOXO3 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 109/558 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs369034038; called by muse, mutect2, varscan2
- FPR3 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 138/491 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV59331854; called by muse, mutect2, varscan2
- FRAT1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 144/501 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs1164247119; called by muse, mutect2, varscan2
- FREM1 | c.4017G>A p.M1339I | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1467385477, COSV101084924; called by muse, mutect2, varscan2
- FREM1 | c.2764G>A p.D922N | Missense Mutation (SNP) | VAF 81/421 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs747401637, COSV66526834; called by muse, mutect2, varscan2
- FREM3 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 153/624 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as rs765394388; called by muse, mutect2, varscan2
- FTO | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.035); catalogued as rs779678337; called by muse, mutect2, varscan2
- FUT9 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 75/314 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs765684352, COSV56142633, COSV56148853; called by muse, mutect2, varscan2
- FYB1 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 54/347 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as COSV60940176, COSV60947622; called by muse, mutect2, varscan2
- FYB2 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 117/322 reads (36%) | catalogued as rs747637853, COSV58589627; called by muse, mutect2, varscan2
- GAB1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 133/466 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs1338997103; called by muse, mutect2, varscan2
- GAL3ST1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 105/554 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs1354255119, COSV58891846, COSV58892092; called by muse, mutect2, varscan2
- GALNT17 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 109/590 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs761319548, COSV61149532, COSV61173595; called by muse, mutect2, varscan2
- GALNT2 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs139591495; called by muse, mutect2, varscan2
- GCSAML | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 102/298 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV63579327; called by muse, mutect2, varscan2
- GHDC | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 187/441 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1199912731; called by muse, mutect2, varscan2
- GIGYF2 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 75/502 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101003753; called by muse, mutect2, varscan2
- GJA1 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 74/360 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.218); catalogued as COSV99246736; called by muse, mutect2, varscan2
- GJA9 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 146/369 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs774074470; called by muse, mutect2, varscan2
- GK2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 86/369 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs149134428, COSV62626058, COSV62628077; called by muse, mutect2, varscan2
- GLB1L3 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs543697948, COSV104435109; called by muse, mutect2, varscan2
- GLDN | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 79/345 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as rs1235082079; called by muse, mutect2, varscan2
- GLI2 | c.2827G>A p.E943K (on ENST00000361492 / NM_001374353.1; = p.E960K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/703 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs1276841941, COSV58037424; called by muse, mutect2, varscan2
- GLI2 | c.3538G>A p.G1180S (on ENST00000361492 / NM_001374353.1; = p.G1197S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 211/611 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as rs1221545910; called by muse, mutect2, varscan2
- GLIS3 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1264261637, COSV100173705; called by muse, mutect2, varscan2
- GLRB | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV100029645, COSV52417998; called by muse, mutect2, varscan2
- GOLGA1 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV65228581; called by muse, mutect2, varscan2
- GOLGA3 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 110/538 reads (20%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs138174554; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1871G>A p.G624E | Missense Mutation (SNP) | VAF 68/852 reads (8%) | SIFT tolerated, low confidence (0.35); catalogued as rs1247966857; called by mutect2, varscan2
- GOLGA6L22 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 41/498 reads (8%) | SIFT tolerated (0.25); catalogued as COSV100320723; called by muse, mutect2
- GPAT3 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 98/413 reads (24%) | catalogued as rs143173203; called by muse, mutect2, varscan2
- GPC2 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 51/344 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs538022806; called by muse, mutect2, varscan2
- GPC5 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 70/311 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs775617391, COSV65582771; called by muse, mutect2, varscan2
- GPD1 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs746425080; called by muse, mutect2, varscan2
- GPNMB | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as rs1432050888, COSV51700285; called by muse, mutect2, varscan2
- GPR27 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 87/433 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.481); catalogued as rs1468201853; called by muse, mutect2, varscan2
- GPR35 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 277/832 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771907692; called by muse, mutect2, varscan2
- GRB10 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 46/602 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs780776923, COSV60010172; called by muse, mutect2
- GREB1L | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 54/337 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs868670954, COSV52550880; called by muse, mutect2, varscan2
- GRID2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 81/420 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs754110902, COSV56172424; called by muse, mutect2, varscan2
- GRIN2A | c.2786C>T p.S929F | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs767268773, COSV58041369; called by muse, mutect2, varscan2
- GRIN2B | c.4255C>T p.P1419S | Missense Mutation (SNP) | VAF 110/507 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101663199; called by muse, mutect2, varscan2
- GRM6 | c.2069C>T p.P690L | Missense Mutation (SNP) | VAF 80/365 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV51436029; called by muse, mutect2, varscan2
- GRM6 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV99179460; called by muse, mutect2, varscan2
- GRM8 | c.2255C>T p.S752L | Missense Mutation (SNP) | VAF 70/404 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.072); catalogued as COSV58830556; called by muse, mutect2, varscan2
- GRM8 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 190/496 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58806253; called by muse, mutect2, varscan2
- GRXCR1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV67671586; called by muse, varscan2
- GTF2E1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.03); catalogued as rs758063838; called by muse, mutect2, varscan2
- GYS2 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 71/373 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV53926502; called by muse, mutect2, varscan2
- H2BW1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 93/427 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.269); catalogued as rs782518895, COSV54220841; called by muse, mutect2, varscan2
- HBB | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 135/348 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs33932070, COSV100092912; ClinVar: other; called by muse, mutect2, varscan2
- HCN1 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 62/158 reads (39%) | catalogued as COSV57491564; called by muse, mutect2, varscan2
- HCN3 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 71/532 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144688517; called by muse, mutect2, varscan2
- HDX | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 118/276 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267606522, COSV52973149; called by muse, mutect2, varscan2
- HECTD4 | c.13049G>A p.G4350E | Missense Mutation (SNP) | VAF 83/437 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs375635285; called by muse, mutect2, varscan2
- HECW1 | c.4270T>C p.S1424P | Missense Mutation (SNP) | VAF 133/355 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV67834613; called by muse, mutect2, varscan2
- HERC1 | c.5734C>T p.R1912C | Missense Mutation (SNP) | VAF 143/343 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1250594628, COSV71247658; called by muse, mutect2, varscan2
- HEXA | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51509046; called by muse, varscan2
- HHLA2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as rs764478334, COSV99071211; called by muse, varscan2
- HID1 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 227/441 reads (51%) | catalogued as rs1332483429, COSV100585933; called by muse, mutect2, varscan2
- HINFP | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 43/363 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760606813, COSV63432352; called by muse, mutect2, varscan2
- HIVEP3 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 192/480 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1388962007; called by muse, mutect2, varscan2
- HMGXB4 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 84/420 reads (20%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as rs1415883925; called by muse, mutect2, varscan2
- HOOK1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 37/270 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969136; called by muse, mutect2, varscan2
- HOXB1 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 84/602 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53317357; called by muse, mutect2, varscan2
- HOXC13 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 89/433 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV99673445; called by muse, mutect2, varscan2
- HPS4 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 69/453 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs2331251, COSV61102968; called by muse, mutect2, varscan2
- HPSE | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs527684134, COSV100264338; called by muse, mutect2, varscan2
- HPSE2 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 81/416 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.641); catalogued as COSV65187926; called by muse, mutect2, varscan2
- HSPA1L | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 100/450 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs770600264, COSV65149092; called by muse, varscan2
- HTR1A | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 203/521 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.157); catalogued as COSV100108823; called by muse, mutect2, varscan2
- HTR2A | c.1212A>C p.K404N | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV66327076; called by muse, mutect2, varscan2
- HTT | c.8828C>T p.P2943L | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV61862348; called by muse, mutect2
- HYDIN | c.4930C>T p.R1644C | Missense Mutation (SNP) | VAF 79/262 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs993703682, COSV59255296; called by muse, mutect2, varscan2
- HYI | c.680G>A p.R227Q (on ENST00000372434 / NM_001330526.2; = p.R202Q on NM_031207.6) | Missense Mutation (SNP) | VAF 53/356 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.066); catalogued as rs773007194; called by muse, mutect2, varscan2
- ICA1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 48/323 reads (15%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.986); catalogued as rs778660693, COSV55579052; called by muse, mutect2, varscan2
- IFI30 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV69576348; called by muse, mutect2, varscan2
- IFIT1B | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1455026168, COSV65663819; called by muse, mutect2, varscan2
- IFNA2 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66505368, COSV66505777; called by muse, mutect2, varscan2
- IFT172 | c.3637G>A p.E1213K | Missense Mutation (SNP) | VAF 105/600 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs760768488; called by muse, mutect2, varscan2
- IGF1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1214292132, COSV61031432; called by muse, varscan2
- IGF2 | c.524G>A p.W175* (on ENST00000434045 / NM_001127598.3; = p.W119* on NM_000612.6) | Nonsense Mutation (SNP) | VAF 226/596 reads (38%) | catalogued as rs868243135, COSV56101911; called by muse, mutect2, varscan2
- IGF2R | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 81/351 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV63628130; called by muse, mutect2, varscan2
- IGFBP4 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 236/462 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV99511192; called by muse, mutect2, varscan2
- IGHG3 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 95/475 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs374103999; called by muse, mutect2, varscan2
- IGHV3-13 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.848); catalogued as rs1555437223; called by muse, mutect2, varscan2
- IGHV3-49 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs541765310; called by muse, varscan2
- IGKV1-8 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 101/370 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.529); catalogued as rs974728367; called by muse, mutect2, varscan2
- IGKV1D-42 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 154/381 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs749575888; called by muse, varscan2
- IGKV2-28 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs1466386564; called by mutect2, varscan2
- IGLJ4 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 68/509 reads (13%) | catalogued as rs767173494; called by muse, mutect2, varscan2
- IGSF10 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 82/304 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs746257775, COSV56792481; called by muse, mutect2, varscan2
- IKZF2 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 57/485 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.721); catalogued as rs769927583, COSV59576522; called by muse, mutect2, varscan2
- IL18RAP | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 164/452 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV51825261, COSV51828191; called by muse, mutect2, varscan2
- IL18RAP | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 79/413 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV51825778; called by muse, mutect2, varscan2
- IL23R | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 46/412 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV61376316; called by muse, mutect2, varscan2
- IL25 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 73/350 reads (21%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs759770968; called by muse, mutect2, varscan2
- IL7R | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57406650; called by muse, mutect2, varscan2
- INF2 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 116/578 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99384450; called by muse, mutect2
- INHBA | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 191/540 reads (35%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.191); catalogued as COSV99637016, COSV99637749; called by muse, varscan2
- INTS6L | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66085729; called by muse, mutect2, varscan2
- IQCA1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 106/668 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1176186919, COSV54515234; called by muse, mutect2, varscan2
- IQCF1 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as rs1236111095; called by muse, varscan2
- IQSEC3 | c.2302G>A p.E768K (on ENST00000538872 / NM_001170738.2; = p.E465K on NM_015232.1) | Missense Mutation (SNP) | VAF 88/495 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as rs782575514, COSV58280759, COSV58281502; called by muse, varscan2
- IQUB | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as rs1267303204; called by muse, mutect2, varscan2
- IRF6 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 43/428 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM092334; called by muse, mutect2, varscan2
- ISX | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58085634; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 63/330 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs1399371668; called by muse, mutect2, varscan2
- ITCH | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.263); catalogued as COSV99392974; called by muse, mutect2, varscan2
- ITGA4 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 60/447 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs201906563, COSV51998072; called by muse, mutect2, varscan2
- ITGAD | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 104/287 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV66759403; called by muse, mutect2, varscan2
- ITGAD | c.3150G>A p.W1050* | Nonsense Mutation (SNP) | VAF 35/246 reads (14%) | catalogued as COSV54932372; called by muse, varscan2
- ITGAV | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53710410; called by muse, mutect2, varscan2
- ITGB3 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 303/564 reads (54%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as rs150951945; called by muse, mutect2, varscan2
- ITPKC | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 65/420 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs904288189, COSV54573896; called by muse, mutect2, varscan2
- ITPR2 | c.4728G>A p.M1576I | Missense Mutation (SNP) | VAF 72/343 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as COSV101189975; called by muse, varscan2
- JAG2 | c.1602G>A p.E534= | Splice Region (SNP) | VAF 70/399 reads (18%) | catalogued as rs1210145719; called by muse, mutect2
- JPH2 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 98/638 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs751173523, COSV100881811; called by muse, mutect2, varscan2
- KALRN | c.2450G>A p.R817Q | Missense Mutation (SNP) | VAF 79/373 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV53754710; called by muse, mutect2, varscan2
- KALRN | c.6482G>A p.R2161K (on ENST00000360013 / NM_001024660.4; = p.R464K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99362034; called by muse, mutect2, varscan2
- KAT7 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 58/464 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52016650; called by muse, mutect2, varscan2
- KBTBD3 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 83/381 reads (22%) | catalogued as rs1330796361, COSV73241195; called by muse, mutect2, varscan2
- KCNA6 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 95/461 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV54974759; called by muse, mutect2, varscan2
- KCND3 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.224); catalogued as rs751093070, COSV56189680; called by muse, mutect2, varscan2
- KCNH2 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 84/546 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV100061231, COSV51133689, COSV51228014; called by muse, mutect2, varscan2
- KCNH7 | c.3302G>A p.R1101Q | Missense Mutation (SNP) | VAF 73/359 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs770314357, COSV59782932; called by muse, mutect2, varscan2
- KCNK13 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 108/411 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs772965269, COSV56411318; called by muse, mutect2, varscan2
- KCNK18 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 55/406 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57973469; called by muse, mutect2, varscan2
- KCNQ3 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 126/508 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1448580874; called by muse, mutect2, varscan2
- KCNU1 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 36/363 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV67753032; called by muse, mutect2, varscan2
- KCP | c.3014C>T p.P1005L (on ENST00000620378; = p.P1065L on NM_001366122.1) | Missense Mutation (SNP) | VAF 102/623 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as rs772885225; called by mutect2, varscan2
- KCTD11 | c.583C>T p.H195Y (on ENST00000333751 / NM_001363642.1; = p.H156Y on NM_001002914.2) | Missense Mutation (SNP) | VAF 140/364 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs1423096454; called by muse, mutect2, varscan2
- KIAA1217 | c.1732C>T p.Q578* | Nonsense Mutation (SNP) | VAF 38/228 reads (17%) | catalogued as COSV56818381; called by muse, mutect2, varscan2
- KIAA1549 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 35/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99652277; called by muse, mutect2
- KIAA1549 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 92/418 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.27); catalogued as rs376519473; called by muse, mutect2, varscan2
- KIAA1586 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs575426890; called by muse, mutect2, varscan2
- KIAA1614 | c.2273C>T p.S758L | Missense Mutation (SNP) | VAF 54/618 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs575391757, COSV62551133; called by muse, mutect2
- KIAA1755 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 86/334 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as COSV54074576; called by muse, mutect2, varscan2
- KIF13B | c.2776C>T p.H926Y | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs771787654, COSV72954513; called by muse, mutect2, varscan2
- KIF21A | c.4099C>T p.R1367C (on ENST00000361418 / NM_001378440.1; = p.R1354C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs756337041, COSV62767529; called by muse, mutect2, varscan2
- KIF26B | c.4205G>A p.R1402Q | Missense Mutation (SNP) | VAF 124/670 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as rs200347978, COSV63643833; called by muse, mutect2, varscan2
- KIF6 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs745653601; called by muse, mutect2, varscan2
- KIR2DL1 | c.962G>C p.R321T | Missense Mutation (SNP) | VAF 182/659 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs1407131464; called by muse, mutect2, varscan2
- KL | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs267603803, COSV66307745; called by muse, mutect2, varscan2
- KLB | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 77/643 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs758838096; called by muse, mutect2, varscan2
- KLHL1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 82/485 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV64771832; called by muse, mutect2, varscan2
- KLHL13 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 83/405 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs182356687, COSV53244944; called by muse, mutect2, varscan2
- KLHL30 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 114/741 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779828832; called by muse, mutect2, varscan2
- KLHL32 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 81/352 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65111804; called by muse, mutect2, varscan2
- KLLN | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 66/461 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs1201621687; called by muse, mutect2, varscan2
- KLRC2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs375539764, COSV101122642; called by muse, mutect2, varscan2
- KMT2B | c.3310C>T p.R1104W | Missense Mutation (SNP) | VAF 134/427 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1403628021; called by muse, mutect2, varscan2
- KMT2B | c.5882C>T p.P1961L | Missense Mutation (SNP) | VAF 232/839 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.373); catalogued as COSV55860331; called by muse, mutect2, varscan2
- KMT5C | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 122/828 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.017); catalogued as rs757162823; called by muse, mutect2, varscan2
- KNDC1 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 227/554 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV58841590; called by muse, mutect2, varscan2
- KRT3 | c.1862A>G p.Q621R | Missense Mutation (SNP) | VAF 90/463 reads (19%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.021); catalogued as COSV100527296; called by muse, mutect2, varscan2
- KRT39 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 62/568 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs145948238; called by muse, mutect2, varscan2
- KRT4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 45/247 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV53409771; called by muse, mutect2, varscan2
- KRTAP10-3 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 106/496 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1555920226, COSV59966762; called by muse, varscan2
- KRTAP10-5 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 46/654 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV59954524, COSV59968821; called by muse, mutect2
- KRTAP10-9 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 111/531 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs1359595548, COSV100555228; called by muse, mutect2, varscan2
- KRTAP5-4 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 90/314 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs1264604225, COSV101294421; called by muse, mutect2, varscan2
- KRTAP9-9 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 215/386 reads (56%) | SIFT deleterious (0); catalogued as rs774844543; called by muse, mutect2, varscan2
- KTN1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68023862; called by muse, mutect2, varscan2
- L1TD1 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.972); catalogued as rs763813062, COSV63133538; called by muse, mutect2, varscan2
- LAMA1 | c.4364C>T p.P1455L | Missense Mutation (SNP) | VAF 65/308 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67544252; called by muse, mutect2, varscan2
- LAMA2 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV104436732; called by muse, mutect2, varscan2
- LAMA3 | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as rs772903420; called by muse, mutect2, varscan2
- LAMB3 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1370865288; called by muse, mutect2, varscan2
- LAMB4 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52715752; called by muse, mutect2, varscan2
- LAMP5 | c.305G>A p.S102N | Missense Mutation (SNP) | VAF 49/524 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1363744729; called by muse, mutect2
- LARP1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 39/304 reads (13%) | PolyPhen benign (0); catalogued as COSV60428127; called by muse, mutect2, varscan2
- LARP4B | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 91/268 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV60223282; called by muse, mutect2, varscan2
- LCE1A | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 108/552 reads (20%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); catalogued as COSV58727006; called by muse, mutect2, varscan2
- LCT | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 85/426 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV51555802; called by muse, mutect2, varscan2
- LCT | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 95/515 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs761296720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDHB | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV63364901; called by muse, mutect2, varscan2
- LEFTY2 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs1228908579; called by muse, mutect2, varscan2
- LEFTY2 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 50/574 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1249268121; called by muse, mutect2
- LGI2 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.342); catalogued as rs1485662889; called by muse, mutect2, varscan2
- LILRA6 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 106/1194 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99063626; called by muse, mutect2
- LIMCH1 | c.3181C>T p.R1061* | Nonsense Mutation (SNP) | VAF 39/316 reads (12%) | catalogued as rs1291153123, COSV58274146, COSV58284304; called by muse, mutect2, varscan2
- LIMK2 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59182243; called by muse, mutect2, varscan2
- LINGO2 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs144926745; called by muse, mutect2, varscan2
- LIPI | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 18/196 reads (9%) | catalogued as COSV60714809; called by muse, mutect2
- LMO3 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs751584255, COSV53781759; called by muse, mutect2, varscan2
- LMX1A | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 66/316 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV54219692; called by muse, varscan2
- LOXHD1 | c.3709G>A p.G1237R | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs935418540, COSV56062898; called by muse, mutect2, varscan2
- LPA | c.3355C>T p.P1119S | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV60307977; called by muse, mutect2, varscan2
- LRFN5 | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 53/351 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99982410; called by muse, mutect2, varscan2
- LRIG1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 75/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs147639877, COSV56250668; called by muse, mutect2, varscan2
- LRP12 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs779021302, COSV99407504; called by muse, mutect2
- LRP1B | c.2441G>A p.G814E | Missense Mutation (SNP) | VAF 126/340 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs775281520, COSV67282551; called by muse, mutect2, varscan2
- LRP1B | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 115/297 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67222488; called by muse, mutect2, varscan2
- LRRC32 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 126/498 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1280897286, COSV99477021; called by muse, mutect2, varscan2
- LRRIQ1 | c.3514C>T p.R1172* | Nonsense Mutation (SNP) | VAF 44/244 reads (18%) | catalogued as rs148400374; called by muse, varscan2
- LRRN1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.428); catalogued as COSV100076412; called by muse, varscan2
- LRRN4 | c.2000G>A p.W667* | Nonsense Mutation (SNP) | VAF 64/444 reads (14%) | catalogued as rs1364254790; called by muse, varscan2
- LSG1 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 85/434 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs750624185; called by muse, mutect2, varscan2
- LTA | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 143/698 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769344065, COSV69305078; called by muse, mutect2, varscan2
- LTBP1 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 108/288 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs546103699, COSV63181992; called by muse, mutect2, varscan2
- LTBP4 | c.2435C>T p.S812L (on ENST00000308370 / NM_001042544.1; = p.S775L on NM_003573.2) | Missense Mutation (SNP) | VAF 153/542 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as rs564851250; called by muse, mutect2, varscan2
- LTO1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 175/501 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as rs372155093; called by muse, varscan2
- LY75 | c.3137G>A p.R1046K | Missense Mutation (SNP) | VAF 78/352 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99717144; called by muse, mutect2, varscan2
- LY9 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54433731, COSV54437167; called by muse, mutect2, varscan2
- M1AP | c.1321C>G p.P441A | Missense Mutation (SNP) | VAF 74/517 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51847721; called by muse, mutect2, varscan2
- MAB21L2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 104/524 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298787047; called by muse, mutect2, varscan2
- MACF1 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 180/459 reads (39%) | catalogued as COSV58369638; called by muse, mutect2, varscan2
- MAGEB5 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 88/449 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as rs181076768, COSV66868711; called by muse, mutect2, varscan2
- MAGEC1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 86/502 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53570262; called by muse, mutect2, varscan2
- MAGEC1 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); catalogued as rs764765365; called by muse, varscan2
- MAGEC1 | c.1457C>A p.S486Y | Missense Mutation (SNP) | VAF 222/491 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.608); catalogued as COSV99594590; called by muse, varscan2
- MAGEC1 | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 206/499 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.549); catalogued as rs866197130, COSV53571500; called by muse, mutect2, varscan2
- MAGEE1 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 92/460 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.855); catalogued as COSV63912015; called by muse, mutect2, varscan2
- MAGI2 | c.3424G>A p.D1142N | Missense Mutation (SNP) | VAF 94/273 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV62684228; called by muse, mutect2, varscan2
- MAGI2 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 124/306 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62663763; called by muse, mutect2, varscan2
- MALRD1 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1475129345; called by muse, mutect2, varscan2
- MAP3K4 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV62330150; called by muse, mutect2, varscan2
- MAP3K5 | c.3880C>T p.P1294S | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs267600831, COSV62889083; called by muse, mutect2, varscan2
- MAP4K3 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 49/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55712364; called by muse, mutect2, varscan2
- MAPK13 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99274803; called by muse, mutect2, varscan2
- MAPKAPK3 | c.630C>T p.A210= | Splice Region (SNP) | VAF 64/273 reads (23%) | catalogued as rs1387018762, COSV63596783; called by muse, mutect2, varscan2
- MAPT | c.745G>A p.G249R (on ENST00000262410 / NM_001377265.1; = p.G174R on NM_016835.4) | Missense Mutation (SNP) | VAF 468/847 reads (55%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.073); catalogued as rs1432673926; called by muse, mutect2, varscan2
- MAST3 | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 197/458 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.964); catalogued as rs576829491; called by muse, mutect2, varscan2
- MBD5 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs772364272, COSV101289867; called by muse, mutect2, varscan2
- MBD5 | c.3656C>T p.P1219L | Missense Mutation (SNP) | VAF 82/369 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as rs1289868922; called by muse, mutect2, varscan2
- MCF2 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV58495475; called by muse, mutect2, varscan2
- MCOLN1 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 113/533 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369993104, COSV51173890; called by muse, mutect2, varscan2
- MDGA2 | c.1855C>T p.R619W (on ENST00000399232 / NM_001113498.2; = p.R321W on NM_182830.4) | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs766117441, COSV62094062; called by muse, mutect2, varscan2
- ME1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs773146004; called by muse, varscan2
- MED12L | c.2286G>C p.E762D | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.956); catalogued as COSV104383326; called by muse, mutect2, varscan2
- MED12L | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 96/397 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56397229; called by muse, mutect2, varscan2
- MED30 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.247); catalogued as rs1412743911; called by muse, mutect2, varscan2
- MEGF10 | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57249059; called by muse, mutect2, varscan2
- MEOX2 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 63/312 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs867233014, COSV56288658; called by muse, mutect2, varscan2
- MEP1A | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 80/340 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1386229821, COSV57919986; called by muse, mutect2, varscan2
- MEPE | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 128/482 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.156); catalogued as rs551712026, COSV63071744, COSV63073982; called by muse, mutect2, varscan2
- MGAM | c.1590G>A p.M530I | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV72075393; called by muse, mutect2
- MGAT5B | c.2054C>T p.P685L (on ENST00000569840 / NM_001199172.2; = p.P683L on NM_144677.3) | Missense Mutation (SNP) | VAF 92/824 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56934779; called by muse, mutect2, varscan2
- MICALL2 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 110/606 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs375884427; called by muse, mutect2, varscan2
- MKLN1 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 35/300 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV61760286; called by muse, mutect2, varscan2
- MKRN3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 82/383 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs140349866; called by muse, mutect2, varscan2
- MLIP | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs146750385; called by muse, mutect2, varscan2
- MLXIPL | c.2351G>A p.G784E | Missense Mutation (SNP) | VAF 63/444 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57667342; called by muse, mutect2, varscan2
- MMD2 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 69/785 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs774820274, COSV68661156; called by muse, mutect2
- MMEL1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 60/481 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs765021621, COSV56526143; called by muse, mutect2, varscan2
- MMP13 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 23/274 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782584939, COSV52823673; called by muse, mutect2
- MMP3 | c.1227G>A p.W409* | Nonsense Mutation (SNP) | VAF 28/168 reads (17%) | catalogued as rs1280008452; called by muse, mutect2, varscan2
- MMRN1 | c.3139C>T p.R1047W | Missense Mutation (SNP) | VAF 65/317 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs368250909, COSV53333695; called by muse, mutect2, varscan2
- MORC4 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 98/427 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV55239939; called by muse, mutect2, varscan2
- MOXD1 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100382037; called by muse, mutect2, varscan2
- MPO | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 72/520 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1247303528, COSV99228517; called by muse, mutect2, varscan2
- MROH2A | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 179/422 reads (42%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.962); catalogued as rs868639543; called by muse, mutect2, varscan2
- MROH2A | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as rs863223390, COSV67681372; ClinVar: benign; called by muse, mutect2, varscan2
- MROH2B | c.2053C>T p.R685* | Nonsense Mutation (SNP) | VAF 33/115 reads (29%) | catalogued as rs377423987; called by muse, mutect2, varscan2
- MRPL48 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.591); catalogued as rs780118362, COSV58638744, COSV58639947; called by muse, varscan2
- MRPS16 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV60285035; called by muse, mutect2, varscan2
- MUC16 | c.36895G>A p.D12299N | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs761092392; called by muse, mutect2, varscan2
- MUC16 | c.25451C>T p.S8484F | Missense Mutation (SNP) | VAF 154/384 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.133); catalogued as rs780878857, COSV101199220; called by muse, mutect2, varscan2
- MUC16 | c.15355C>T p.P5119S | Missense Mutation (SNP) | VAF 101/254 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV67449282; called by muse, mutect2, varscan2
- MUC16 | c.14602G>A p.E4868K | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.205); catalogued as COSV67484099; called by muse, mutect2, varscan2
- MUC16 | c.14601G>A p.M4867I | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); catalogued as rs550349238, COSV67442601; called by muse, mutect2, varscan2
- MUC4 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 124/669 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.316); catalogued as COSV62131694; called by muse, mutect2, varscan2
- MUC4 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 125/577 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV100640474; called by muse, mutect2, varscan2
- MUC5B | c.9220C>T p.L3074F | Missense Mutation (SNP) | VAF 95/689 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs778083835; called by muse, mutect2, varscan2
- MUC6 | c.6212C>T p.T2071I | Missense Mutation (SNP) | VAF 57/706 reads (8%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs749553046; called by muse, mutect2
- MUC6 | c.3977G>A p.R1326Q | Missense Mutation (SNP) | VAF 101/772 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs201742888; called by muse, mutect2, varscan2
- MUC6 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 108/823 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs1206334964, COSV101424561; called by muse, mutect2, varscan2
- MYCN | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 203/549 reads (37%) | catalogued as COSV99808583; called by muse, mutect2, varscan2
- MYF6 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99952956; called by muse, mutect2, varscan2
- MYH3 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 114/292 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1160002369, COSV56864439; called by muse, mutect2, varscan2
- MYH4 | c.5224C>T p.Q1742* | Nonsense Mutation (SNP) | VAF 74/176 reads (42%) | catalogued as COSV55113351; called by muse, mutect2, varscan2
- MYH4 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV55121228; called by muse, mutect2, varscan2
- MYO15A | c.5762G>A p.R1921Q | Missense Mutation (SNP) | VAF 225/462 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as rs763685950, COSV52757036; called by muse, mutect2, varscan2
- MYO15B | c.6019C>T p.P2007S | Missense Mutation (SNP) | VAF 105/616 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1368368184; called by muse, mutect2, varscan2
- MYO1A | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267603596; called by muse, mutect2
- MYO1E | c.2852C>T p.P951L | Missense Mutation (SNP) | VAF 120/291 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs750410945; called by muse, mutect2, varscan2
- MYO7A | c.2716C>T p.R906C | Missense Mutation (SNP) | VAF 76/426 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs868923965, COSV68683826; called by muse, mutect2, varscan2
- MYO7B | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 159/422 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as rs1331403857, COSV67345024; called by muse, mutect2, varscan2
- MYO7B | c.3862G>A p.E1288K | Missense Mutation (SNP) | VAF 101/577 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs758529828, COSV67346180; called by muse, mutect2, varscan2
- MYO7B | c.5080G>A p.D1694N | Missense Mutation (SNP) | VAF 303/751 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs373648776; called by muse, mutect2, varscan2
- MYO9A | c.6292C>T p.R2098* | Nonsense Mutation (SNP) | VAF 145/300 reads (48%) | catalogued as rs866994109; called by muse, mutect2, varscan2
- MYOF | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63708298; called by muse, mutect2, varscan2
- MYT1L | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 188/504 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67709081; called by muse, mutect2, varscan2
- N4BP2 | c.2765C>T p.S922F | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV54703431; called by muse, mutect2, varscan2
- NAALADL2 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as rs373491589, COSV71984352; called by muse, mutect2, varscan2
- NAP1L2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 122/510 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.632); catalogued as COSV100999171; called by muse, varscan2
- NAP1L3 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 100/510 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.382); catalogued as COSV59078213; called by muse, mutect2, varscan2
- NAP1L5 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 68/730 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1212893392, COSV99985774; called by muse, mutect2
- NAT8L | c.705C>G p.F235L | Missense Mutation (SNP) | VAF 156/617 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV59051635; called by muse, mutect2, varscan2
- NAV1 | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 78/506 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs771196258; called by muse, varscan2
- NCF1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 82/826 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56877479; called by muse, mutect2
- NCF4 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 59/393 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as COSV50625284; called by muse, mutect2, varscan2
- NCOA1 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 86/520 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs904180131, COSV56044336; called by muse, mutect2, varscan2
- NCSTN | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs770064036; called by muse, mutect2
- NEBL | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.966); catalogued as rs1060503679, COSV65803121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK11 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs142683282; called by muse, mutect2, varscan2
- NEXMIF | c.1371G>T p.K457N | Missense Mutation (SNP) | VAF 118/575 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV99282196; called by muse, mutect2, varscan2
- NFASC | c.2162G>A p.R721Q (on ENST00000339876 / NM_001378329.1; = p.R717Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/388 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.066); catalogued as rs768730398, COSV58364055; called by muse, mutect2
- NFIX | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 61/343 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV62175687; called by muse, mutect2, varscan2
- NFKBIA | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 99/486 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs376762724; called by muse, mutect2, varscan2
- NLRP12 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 155/374 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs147810259; called by muse, mutect2, varscan2
- NLRP13 | c.3104C>T p.S1035L | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs199475879, COSV100738637, COSV61621599; ClinVar: not provided; called by muse, mutect2, varscan2
- NLRP14 | c.2657C>T p.S886L | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs891431323; called by muse, mutect2
- NLRP3 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 48/414 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.751); catalogued as COSV60223275; called by muse, mutect2, varscan2
- NLRP7 | c.369G>A p.W123* | Nonsense Mutation (SNP) | VAF 132/436 reads (30%) | catalogued as COSV60179036; called by muse, mutect2, varscan2
- NLRP8 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 156/536 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV52591112; called by muse, varscan2
- NLRP8 | c.2257G>A p.G753S | Missense Mutation (SNP) | VAF 120/417 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs763415898; called by muse, mutect2, varscan2
- NLRP9 | c.2047C>T p.H683Y | Missense Mutation (SNP) | VAF 93/397 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as rs780947756, COSV60467790; called by muse, mutect2, varscan2
- NLRP9 | c.741G>A p.W247* | Nonsense Mutation (SNP) | VAF 155/508 reads (31%) | catalogued as COSV60463821; called by muse, mutect2, varscan2
- NMNAT3 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs774032862, COSV56158540; called by muse, mutect2, varscan2
- NNMT | c.602G>A p.S201N | Missense Mutation (SNP) | VAF 169/459 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.439); catalogued as COSV55474359; called by muse, mutect2, varscan2
- NOL6 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs531563377; called by muse, mutect2, varscan2
- NOS3 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 62/589 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs764127718; called by muse, mutect2
- NOX5 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 342/651 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV99534944; called by muse, mutect2, varscan2
- NPHP1 | c.1787G>A p.R596K (on ENST00000393272 / NM_207181.4; = p.R597K on NM_000272.5) | Missense Mutation (SNP) | VAF 47/333 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs766499997; called by muse, mutect2, varscan2
- NPHS1 | c.3266G>A p.R1089K | Missense Mutation (SNP) | VAF 94/330 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs113252496; called by muse, mutect2, varscan2
- NPIPA5 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 54/608 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1303667994; called by muse, mutect2
- NPS | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV104432609, COSV67690678; called by muse, mutect2, varscan2
- NRCAM | c.331G>A p.E111K (on ENST00000379028 / NM_001371124.1; = p.E105K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/662 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as rs140770274, COSV61036331; called by muse, mutect2
- NRK | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1166798144, COSV54589199; called by muse, mutect2, varscan2
- NRK | c.3032G>A p.G1011E | Missense Mutation (SNP) | VAF 190/487 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1347043783; called by muse, mutect2, varscan2
- NRP2 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs935324633, COSV99783311; called by muse, mutect2, varscan2
- NRXN1 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 87/570 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58463010; called by muse, mutect2, varscan2
- NRXN1 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 66/420 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58436858; called by muse, mutect2, varscan2
- NT5C1B | c.796G>A p.E266K (on ENST00000359846 / NM_001199086.2; = p.E206K on NM_033253.4) | Missense Mutation (SNP) | VAF 209/542 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); catalogued as rs781054410, COSV58394503; called by muse, varscan2
- NT5DC4 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 61/380 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.132); catalogued as rs1401573930; called by muse, mutect2, varscan2
- NT5E | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 82/335 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs946909778; called by muse, mutect2, varscan2
- NTRK3 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 128/273 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.088); catalogued as COSV58144872; called by muse, mutect2, varscan2
- NUDT12 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.649); catalogued as rs544325116, COSV50090562; called by muse, mutect2, varscan2
- NUDT8 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 58/578 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1342759139; called by muse, mutect2
- NVL | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 54/498 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs866683945, COSV55869764, COSV55874438; called by muse, mutect2, varscan2
- OCIAD2 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56717356, COSV99906582; called by muse, mutect2, varscan2
- OLFM3 | c.875G>A p.G292E (on ENST00000338858 / NM_001288821.1; = p.G272E on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58796045; called by muse, mutect2, varscan2
- OR10A3 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 45/440 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62459253, COSV62460367; called by muse, mutect2, varscan2
- OR13C2 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 65/392 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101604882; called by muse, mutect2, varscan2
- OR14C36 | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58600698, COSV58601240; called by muse, mutect2, varscan2
- OR14C36 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 43/354 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs1351356830, COSV58601692; called by muse, mutect2, varscan2
- OR1D2 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.338); catalogued as rs781467802; called by muse, mutect2, varscan2
- OR2A12 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV68822080; called by muse, mutect2
- OR2AE1 | c.281T>C p.F94S | Missense Mutation (SNP) | VAF 108/558 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as COSV60391258; called by muse, mutect2, varscan2
- OR2AK2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 73/331 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs764277744, COSV63550170; called by muse, mutect2, varscan2
- OR2AP1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 77/343 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV58725555; called by muse, mutect2, varscan2
- OR2C3 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 62/457 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs762142020, COSV63576357; called by muse, mutect2, varscan2
- OR2D3 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 44/378 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99549715; called by muse, mutect2, varscan2
- OR2F1 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 67/480 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV67331227, COSV67331259; called by muse, mutect2, varscan2
- OR2J2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 86/423 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs761974714; called by muse, mutect2, varscan2
- OR2T12 | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV58777466; called by muse, mutect2, varscan2
3,134 further variants in this file (1,762 protein-altering or splice-affecting, 1,216 silent, 156 other) are not listed here.
